Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8339, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8339-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

█ y/o male with left renal mass with lymphadenopathy. R/o renal cell cancer.

Specimens Submitted:

- 1: SP: Left kidney and portion of left adrenal, total nephrectomy █
- 2: SP: Lymph nodes, Para-aortic, excision: (█)
- 3: SP: Lymph nodes, Pre-aortic, excisions █
- 4: SP: Lymph nodes, Interaortocaval, excision █
- 5: SP: Lymph nodes, Suprahilar and portion of left adrenal, excision █
- 6: SP: Liver, left lobe, biopsy: █

DIAGNOSIS:

1. SP: Left kidney and portion of left adrenal, total nephrectomy █

Tumor Type:

Renal cell carcinoma - Chromophobe type

Tumor Size:

Greatest diameter is 13.0 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia
Involves renal hilar fat

Renal Vein Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

2. SP: Lymph nodes, Para-aortic, excision:

Lymph Nodes:

Not involved

Number of nodes examined:15

3. SP: Lymph nodes, Pre-aortic, excisions:

Lymph Nodes:

Not involved

Number of nodes examined:12

4. SP: Lymph nodes, Interaortocaval, excision:

Lymph Nodes:

Not involved

Number of nodes examined:2

5. SP: Lymph nodes, Suprahilar and portion of left adrenal, excision:

Lymph Nodes:

Number of nodes examined:4

Number of metastatic nodes:1

The largest metastatic node is 1.3cm

Perinodal (extracapsular) extension not identified

Unremarkable adrenal gland

6. Liver, left lobe, biopsy:

- Metastatic renal cell carcinoma, chromophobe type, involving liver parenchyma.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain

Comment

MIB-1 (Ki-67)

IMM RECUT

NEG CONT

RECUT

RECUT

RECUT

RECUT

RECUT

RECUT

RECUT

RECUT

RECUT

RECUT

Gross Description:

1) The specimen is received fresh labeled "left kidney and portion of left adrenal" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 1258 g in total. The kidney measures 13x12x10 cm. The attached ureter measures

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

1.0 cm in length and 0.5 cm in diameter. The attached renal vein measures 1.0 cm in length and 1.0 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 4.0x1.0x1.0 cm. The kidney is inked black and bivalved to reveal a large necrotic mass, completely replacing the entire kidney with rim normal renal parenchyma in the hilar area and measuring 13x12x10cm. Tumor thrombus is identified in the renal vein, but the margin is free of tumor. The renal cortex measures 0.5 cm in thickness and the calyces appear involved by the tumor. The specimen is photographed. Representative sections are submitted for [REDACTED] and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
T-- tumor
TH--tumor in the hilar area
TK -- tumor with adjacent kidney
Thr-tumor thrombus
K -- representative sections kidney
AD -- adrenal gland
HF-hilar fat

2). The specimen is received in formalin, labeled "Para-aortic nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.6 to 3 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes

3). The specimen is received in formalin, labeled "Pre-aortic nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.6 to 2.6 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes

4). The specimen is received in formalin, labeled "Interaortocaval lymph node" and consists of two pink tan firm lymph nodes measuring from 0.8 and 2.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph node

5). The specimen is received in formalin, labeled "Suprahilar nodes and portion of left adrenal" and consists of a piece of brown tan fibrous adipose tissue measuring 6 x 2.7 x 1.3 cm. Multiple pink tan firm lymph nodes are isolated ranging from 1 to 1.6 cm in greatest dimension. All identified lymph nodes are submitted. A golden yellow portion of adrenal gland is identified measuring 3.5 x 2.2 x 1 cm. Serial sections of the gland reveal a homogeneous golden yellow parenchyma and is entirely submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes
U- sections from adrenal gland

6). The specimen is received in formalin, labeled "Biopsy left lobe of liver" and consists of a portion of brown-tan firm liver tissue measuring 1.4 x 0.6 x 0.3 cm. The surgical margin is inked in black and the specimen is bisected and entirely submitted.

Summary of sections:

U-undesignated

Summary of Sections:

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Part 1: SP: Left kidney and portion of left adrenal, total nephrectomy

Block	Sect. Site	PCs
1	ad	1
2	hf	2
1	k	1
7	t	7
2	th	2
1	thr	1
1	tk	1
1	uvm	1

Part 2: SP: Lymph nodes, Para-aortic, excision:

Block	Sect. Site	PCs
4	BLN	6
3	LN	6

Part 3: SP: Lymph nodes, Pre-aortic, excisions

Block	Sect. Site	PCs
4	BLN	6
3	LN	4

Part 4: SP: Lymph nodes, Interaortocaval, excision:

Block	Sect. Site	PCs
2	BLN	2
1	LN	1

Part 5: SP: Lymph nodes, Suprahilar and portion of left adrenal, excision

Block	Sect. Site	PCs
2	BLN	4
1	LN	2
4	U	4

Part 6: SP: Liver, left lobe, biopsy:

Block	Sect. Site	PCs
1	U	2

Source: NCI Genomic Data Commons file 188f6581-9bc8-4e0c-8f9b-15593223e3dd (TCGA-KL-8339.73432CD8-3EDC-42D2-ACD6-09C1E72E81F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).